Somatic mutation profile of tumor specimen 0DGOAS from CCDI case PBBTTG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain stem; Age at diagnosis: 11.9 years (4,349 days).
Specimen 0DGOAS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8f53352-b40d-4270-a8c1-5d3e089de993.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGOBD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d40e51a-b7b9-424c-8fc2-604e233bb2ed

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 5, Intron 1, In Frame Del 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 147/422 reads (35%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CDH8 | c.92C>G p.P31R | Missense Mutation (SNP) | VAF 159/531 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.43); catalogued as COSV100183866, COSV54901521; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.936_941delinsAGTT p.N312Kfs*12 (on ENST00000354667 / NM_031243.3; = p.N300Kfs*12 on NM_002137.4) | Frame Shift Del (DEL) | VAF 106/505 reads (21%) | called by pindel, varscan2*
- ITGA2 | c.1670C>G p.A557G | Missense Mutation (SNP) | VAF 28/776 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); called by muse, mutect2
- OR52N4 | c.581T>C p.V194A | Missense Mutation (SNP) | VAF 52/618 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2
- PCDH15 | c.4687A>G p.M1563V (on ENST00000644397 / NM_001354429.2; = p.M1505V on NM_001142771.2) | Missense Mutation (SNP) | VAF 101/206 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- PCGF2 | c.79dup p.D27Gfs*31 | Frame Shift Ins (INS) | VAF 218/613 reads (36%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1705_1728del p.D569_T576del (on ENST00000521381 / NM_181523.3; = p.D299_T306del on NM_181504.4) | In Frame Del (DEL) | VAF 130/486 reads (27%) | called by pindel, varscan2
- TAF1L | c.4576T>A p.F1526I | Missense Mutation (SNP) | VAF 339/915 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- WDR87 | c.5150A>T p.E1717V | Missense Mutation (SNP) | VAF 200/621 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- BFSP2 | c.975G>A p.S325= | Silent (SNP) | VAF 202/535 reads (38%) | catalogued as rs781313814; called by muse, mutect2, varscan2
- GALNT10 | c.828C>T p.Y276= | Silent (SNP) | VAF 242/603 reads (40%) | catalogued as rs770121388, COSV51732623, COSV51733628; called by muse, mutect2, varscan2
- LAMB4 | c.1146G>A p.P382= | Silent (SNP) | VAF 209/642 reads (33%) | catalogued as rs757765055; called by muse, mutect2, varscan2
- PCSK1N | c.471G>A p.A157= | Silent (SNP) | VAF 262/839 reads (31%) | called by muse, mutect2, varscan2
- ZNF727 | c.1425T>A p.T475= | Silent (SNP) | VAF 130/314 reads (41%) | called by muse, mutect2, varscan2
- CCR2 | c.941+176G>T | Intron (SNP) | VAF 32/191 reads (17%) | called by muse, mutect2, varscan2
